Somatic mutation profile of tumor specimen BLGSP-71-06-00254-01A (aliquot BLGSP-71-06-00254-01A-01D-A663-33) from CGCI case BLGSP-71-06-00254, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.2 years (2,253 days).
Specimen BLGSP-71-06-00254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20fe2a87-a9b1-4dd3-bb7f-f0f4de1082b3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00254-12A (Buccal Cell Normal), aliquot BLGSP-71-06-00254-12A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9c0c039-4713-41e5-b4d6-c95fd30c37fa

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 3, 5'UTR 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5000dup p.E1668Gfs*30 | Frame Shift Ins (INS) | VAF 103/267 reads (39%) | catalogued as COSV61389037; called by mutect2, pindel, varscan2
- DDX3X | c.1460G>T p.R487L (on ENST00000399959; = p.R488L on NM_001356.5) | Missense Mutation (SNP) | VAF 269/296 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as CM158043, COSV67864331; called by muse, mutect2, varscan2
- KMT2D | c.15289C>T p.R5097* | Nonsense Mutation (SNP) | VAF 110/251 reads (44%) | catalogued as COSV56421006; called by muse, mutect2, varscan2
- BCR | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXO1 | c.484A>G p.N162D | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- BACH2 | c.-446+969C>T | Intron (SNP) | VAF 23/54 reads (43%) | called by muse, varscan2
- CXCR4 | c.15+507C>G | Intron (SNP) | VAF 18/306 reads (6%) | catalogued as COSV54016609; called by muse, mutect2
- MYC | c.-408A>T | 5'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, varscan2
- MYC | c.-353G>C | 5'UTR (SNP) | VAF 15/40 reads (38%) | catalogued as rs1254681892, COSV104388372; called by muse, varscan2
- SGK1 | c.152+148T>C | Intron (SNP) | VAF 172/341 reads (50%) | catalogued as COSV52805507; called by muse, mutect2, varscan2
